Surgical pathology report (de-identified scan), TCGA case TCGA-EK-A3GM, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Gynecologic Oncology Group, specimen TCGA-EK-A3GM-01A (Primary Tumor).

[page 1 of 5]
Surgical Pathology Final Report

Result type:
Result date:
Result status:
Result title:
Performed by:
Verified by:
Encounter info:

lw 11/29/11

* Final Report *

Surgical Procedure

Patient Name:
DOB:
Account Number:
Attending Physician:
Ordering Physician:
Accession #:
Date Collected:

SPECIMEN A: CERVIX BX
SPECIMEN B: CERVIX TISSUE (PORTION FOR
CLINICAL HISTORY:

100-0-3

adenocarcinoma, endocervical type 8384/3
Site: cervix, NOS C53.9 lw 11/29/11

SPECIMENS SUBMITTED:

A. CERVIX BX
B. CERVIX TISSUE (PORTION FOR

DIAGNOSIS:

A, B. CERVIX; BIOPSY:

ADENOCARCINOMA, ENDOCERVICAL ORIGIN, MODERATELY DIFFERENTIATED.
TUMOR IS PRESENT AS DISAGGREGATED FRAGMENTS OF TISSUE.

COMMENT:

Tumor cells are strongly positive for monoclonal CEA and p16 with no reactivity for estrogen receptor and vimentin by immunohistochemical staining using appropriate positive and negative controls. These immunohistochemical results are consistent with an endocervical rather than endometrial origin for the tumor.

INTRA-OPERATIVE DIAGNOSIS:

A. Cervical biopsy: High grade carcinoma with glandular features.

CLINICAL INFORMATION:

65-year old female with history of hypertension, now with cervical mass 5.0 cm. Preintraoperative diagnosis: cervical carcinoma.

GROSS DESCRIPTION:

There are two containers, each labeled with the patient's name and medical record number.

Labeled "frozen section cervical biopsy". Received unfixed are multiple

Printed by:
Printed on:

[page 2 of 5]
Surgical Pathology Final Report

portions of pink-tan soft tissue aggregating to 1.5 x 1.5 x 0.7 cm. Representative sections are submitted for frozen section, wrapped and submitted for permanent in cassette A1. The remaining tissue is submitted for permanent in cassette A2.

Labeled "cervical biopsy". Received unfixed are multiple portions of purple-red soft tissue aggregating to 1.0 x 1.0 x 0.3 cm. A representative section is wrapped and submitted for permanent in cassette B1. The remaining tissue is submitted for [REDACTED] per consent from the patient.

MICROSCOPIC DESCRIPTION:

Histologic examination performed.

TUMOR STAGING FORM:

CERVIX UTERI

AMERICAN JOINT COMMITTEE ON CANCER STAGING MANUAL SIXTH EDITION 2002

DEFINITIONS

Primary Tumor (T)

Clin Path TNM FIGO

Categories Stages Definitions

- | | | | |
|--------------------------|--------------------------|------|--|
| ☐ | ☐ | TX | Primary tumor cannot be assessed |
| ☐ | ☐ | T0 | No evidence of primary tumor |
| ☐ | ☐ | Tis | 0 Carcinoma in situ |
| ☐ | ☐ | T1 | 1 Cervical carcinoma confined to uterus
(extension to corpus should be disregarded) |
| ☐ | ☐ | T1a | 1A Invasive carcinoma diagnosed only by
microscopy. (Note 1: The depth of invasion is
defined as the measurement of the tumor from
the epithelial-stromal junction of the adjacent
most superficial dermal papilla to the deepest
point of invasion.) All macroscopically
visible lesions - even with superficial
invasion - are T1b/1B. Stromal invasion with a
maximal depth of 5.0 mm measured from the base
of the epithelium and a horizontal spread of
7.0 mm or less. Vascular space involvement,
venous or lymphatic, does not affect
classification |
| ☐ | ☐ | T1a1 | 1A1 Measured stromal invasion 3.0 mm or less in
depth and 7.0 mm or less in horizontal spread |
| ☐ | ☐ | T1a2 | 1A2 Measured stromal invasion more than 3.0 mm and
not more than 5.0 mm with a horizontal spread
7.0 mm or less |
| ☐ | ☐ | T1b | 1B Clinically visible lesion confined to the
cervix or microscopic lesion greater than
T1a2/1A2 |
| ☐ | ☐ | T1b1 | 1B1 Clinically visible lesion 4.0 cm or less in
greatest dimension |
| ☐ | ☐ | T1b2 | 1B2 Clinically visible lesion more than 4.0 cm in |

Printed by:
Printed on:

Page 2 of 5
(Continued)

[page 3 of 5]
Surgical Pathology Final Report

- greatest dimension
- ☐ ☐ T2 II Cervical carcinoma invades beyond uterus but not to pelvic wall or to lower third of vagina
- ☐ ☐ T2a IIA Tumor without parametrial invasion
- ☐ ☐ T2b IIB Tumor with parametrial invasion
- ☐ ☐ T3 III Tumor extends to pelvic wall and/or involves lower third of vagina and/or causes hydronephrosis or non-functioning kidney
- ☐ ☐ T3a IIIA Tumor involves lower third of vagina, no extension to pelvic wall
- ☐ ☐ T3b IIIB Tumor extends to pelvic wall and/or causes hydronephrosis or non-functioning kidney
- ☐ ☐ T4 IVA Tumor invades mucosa of bladder or rectum and/or extends beyond true pelvis (bullous edema is not sufficient evidence to classify a tumor as T4)

Regional Lymph Nodes (N)

- ☐ ☐ NX Regional lymph nodes cannot be assessed
- ☐ ☐ N0 No regional lymph node metastasis
- ☐ ☐ N1 Regional lymph node metastasis

Distant Metastasis (M)

- ☐ ☐ MX Distant metastasis cannot be assessed
- ☐ ☐ M0 No distant metastasis
- ☐ ☐ M1 IVB Distant metastasis
- Biopsy of metastatic site performed ☐ Y ☐ N
- Source of pathologic metastatic specimen _____

Stage Grouping (AJCC/UICC/FIGO)

- ☐ ☐ 0 Tis N0 M0
- ☐ ☐ I T1 N0 M0
- ☐ ☐ IA T1a N0 M0
- ☐ ☐ IA1 T1a1 N0 M0
- ☐ ☐ IA2 T1a2 N0 M0
- ☐ ☐ IB T1b N0 M0
- ☐ ☐ IB1 T1b1 N0 M0
- ☐ ☐ IB2 T1b2 N0 M0
- ☐ ☐ II T2 N0 M0
- ☐ ☐ IIA T2a N0 M0
- ☐ ☐ IIB T2b N0 M0
- ☐ ☐ III T3 N0 M0
- ☐ ☐ IIIA T3a N0 M0
- ☐ ☐ IIIB T1 N1 M0
- ☐ ☐ T2 N1 M0
- ☐ ☐ T3a N1 M0
- ☐ ☐ T3b Any N M0
- ☐ ☐ IVA T4 Any N M0
- ☐ ☐ IVB Any T Any N M1

Histologic Grade (G)

- ☐ GX Grade cannot be assessed

Printed by:
Printed on:

[page 4 of 5]
Surgical Pathology Final Report

- ☐ G1 Well differentiated
- ☐ G2 Moderately differentiated
- ☐ G3 Poorly differentiated
- ☐ G4 Undifferentiated

Residual Tumor (R)

- ☐ RX Presence of residual tumor cannot be assessed
- ☐ R0 No residual tumor
- ☐ R1 Microscopic residual tumor
- ☐ R2 Macroscopic residual tumor

Additional Descriptors

For identification of special cases of TNM or pTNM classifications, the "m" suffix and "y," "r," and "a" prefixes are used. Although they do not affect the stage grouping, they indicate cases needing separate analysis.

- ☐ m suffix indicates the presence of multiple primary tumors in a single site and is recorded in parentheses: pT(m)NM.
- ☐ y prefix indicates those cases in which classification is performed during or following initial multimodality therapy. The cTNM or pTNM category is identified by a "y" prefix. The ycTNM or ypTNM categorizes the extent of tumor actually present at the time of that examination. The "y" categorization is not an estimate of tumor prior to multimodality therapy.
- ☐ r prefix indicates a recurrent tumor when staged after a disease-free interval, and is identified by the "r" prefix: rTNM.
- ☐ a prefix designates the stage determined at autopsy: aTNM.

Notes

Additional Descriptors

Lymphatic Vessel Invasion (L)

- LX Lymphatic vessel invasion cannot be assessed
- L0 No lymphatic vessel invasion
- L1 Lymphatic vessel invasion

Venous Invasion (V)

- VX Venous invasion cannot be assessed
- V0 No venous invasion
- V1 Microscopic venous invasion
- V2 Macroscopic venous invasion

Prognostic Indicators (if applicable)

Physician's Signature _____ Date: _____

The staff pathologist was present during the formal review and interpretation of all slides and ancillary studies, (if performed), with the medical student or resident.

Printed by:
Printed on:

[page 5 of 5]
Surgical Pathology Final Report

Rendering Diagnostician:
Pathologist
Electronically Signed

Completed Action List:

Printed by:
Printed on:

Page 5 of 5
(End of Report)

Source: NCI Genomic Data Commons file 1f6a8c4e-62e0-4c47-b5a8-a45cbffc1abc (TCGA-EK-A3GM.15E809A3-4A09-426E-B816-C31246ECCCA4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).